Gene-level copy-number profile of tumor specimen BLGSP-71-06-00081-01E from CGCI case BLGSP-71-06-00081, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00081-01E: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 41ee1254-75b1-4c54-a786-2ecf62c84e22.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00081-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,762 have no estimate.
https://portal.gdc.cancer.gov/files/3ea8ac4e-e12e-4cde-88b5-e282fc6802a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 3,050; copy number 2: 54,670; copy number 3: 935; copy number 4: 37; copy number 5: 33; copy number 6: 19; copy number 8: 5; copy number 9: 5; copy number 10: 7; copy number 11: 1; copy number 36: 1; copy number 65: 4.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,234,912, 40 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr2:90,220,727–90,221,384, 1 gene: IGKV1D-8.
- chr8:7,312,846–7,338,707, 3 genes (within-gene range 0–3): DEFB109B, USP17L1, USP17L4.
- chr14:105,851,705–106,108,464, 49 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,190,901–7,191,563, 1 gene, copy number 36: RPS3AP33.
- chr8:7,238,286–7,298,024, 8 genes, copy number 6: AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P.
- chr8:12,182,096–12,194,133, 1 gene, copy number 5 (within-gene range 2–5): FAM86B1.
- chr8:12,205,759–12,206,389, 1 gene, copy number 5: ENPP7P12.
- chr8:12,310,962–12,318,316, 1 gene, copy number 8: DEFB130A.
- chr8:12,341,426–12,345,776, 1 gene, copy number 11: DEFB108E.
- chr9:66,253,424–66,642,277, 3 genes, copy number 8: CDRT15P12, RBPJP2, RAB28P4.
- chr10:48,009,873–48,031,640, 1 gene, copy number 5: AGAP12P.
- chr14:18,333,726–18,412,264, 3 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2.
- chr15:32,359,538–32,367,784, 1 gene, copy number 8: AC139426.2.
- chr15:32,436,503–32,500,346, 6 genes, copy number 5–9: DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3.
- chr17:19,061,912–19,112,636, 8 genes, copy number 6–10: SNORD3B-1, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D.
- chr17:19,188,016–19,214,045, 4 genes, copy number 65: SNORD3A, SNORD3C, AC106017.1, KYNUP3.
- chr17:46,274,784–46,361,797, 3 genes, copy number 6: ARL17B, LRRC37A, RN7SL656P.
- chr21:7,744,962–8,680,934, 28 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr22:18,833,694–18,894,407, 5 genes, copy number 6–9: E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 197. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
